Gene-level copy-number profile of tumor specimen HCM-WCMC-0673-C56-01A from HCMI case HCM-WCMC-0673-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIA2; FIGO stage: Stage III; Age at diagnosis: 32.9 years (12,015 days).
Specimen HCM-WCMC-0673-C56-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file be9ca01f-7073-4818-a272-146df1dd6df9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0673-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/7f4cb94d-541d-4565-8bdd-6de0dd22c3c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 1,188; copy number 2: 57,137; copy number 3: 41; copy number 4: 8; copy number 5: 3; copy number 6: 1; copy number 8: 1; copy number 16: 2.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:195,720,884–195,741,123, 1 gene (within-gene range 0–2): MUC20.
- chr5:32,646,564–32,651,976, 1 gene: LINC02061.
- chr7:56,805,336–56,808,148, 1 gene: CICP28.
- chr8:22,613,908–22,616,657, 1 gene (within-gene range 0–2): AC037459.2.
- chr16:543,277–553,847, 2 genes (within-gene range 0–2): MIR3176, Z97986.1.
- chr16:1,065,240–1,066,502, 1 gene (within-gene range 0–2): AC009041.2.
- chr16:15,125,242–15,154,564, 3 genes (within-gene range 0–2): PKD1P6, MIR6511B2, Y_RNA.
- chr17:81,451,104–81,451,188, 1 gene (within-gene range 0–2): MIR3186.
- chr21:43,789,513–43,812,567, 2 genes: RRP1, AATBC.
- chr22:18,951,934–18,959,512, 1 gene: AC007326.2.
- chr22:45,875,999–45,977,162, 2 genes (within-gene range 0–2): BX324167.1, WNT7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:23,272,422–23,302,859, 3 genes, copy number 5 (within-gene range 2–5): HOMEZ, H3P37, PPP1R3E.
- chr22:18,873,543–18,914,238, 3 genes, copy number 6–16 (within-gene range 2–16): FAM230F, AC008103.1, DGCR6.
- chr22:18,936,411–18,947,741, 1 gene, copy number 8 (within-gene range 2–8): AC007326.5.

Autosomal genes at a single copy (total copy number 1): 1,188. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
